Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8680, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8680-01A (Primary Tumor).

[page 1 of 3]
[illegible]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
In lesser curvature, there is an ulcerated tumor, with 3x3x1cm in size, firm and gray surface.	Mucosa is ulcerated. Tumor is invasion into serosa. Tumor is composed of tubules containing necrosis or trabeculae. Glands are variability in size and shape. Tumor cells are moderately straitified. Mitotic index is present. Nuclei are hyperchromatic and irregularly enlarged and prominent nucleoli. Stroma is invasion of prominent lymphocytes. Tumor is necrotic.	Tubular adenocarcinoma, moderately-differentiated, infiltrating serosa

[page 3 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Antrum Tumor size: 3 x 3 x 1 cm Tumor features: Ulcerated Histologic type: Tubular adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 3/10 positive for metastasis (Adjacent lymph node 3/10) Lymphatic invasion: Present Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 7011a5fa-8512-4962-904a-2674f2be00bd (TCGA-BR-8680.90414042-1CDA-4DA6-B2E6-0DCE995A8B8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).